Gene-level copy-number profile of tumor specimen C3N-03876-01 (profiled together with C3N-03876-02) from CPTAC case C3N-03876, project CPTAC-3 (Larynx — Squamous Cell Neoplasms). Sex at birth: male; Vital status: Dead; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Larynx, NOS; AJCC pathologic stage: Stage IVA; Tumor grade: G1; Age at diagnosis: 65.3 years (23,849 days).
Specimen C3N-03876-01: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Larynx; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file 6390cf41-a6a4-4a4d-b4f7-08bf31a273e7.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator C3N-03876-31 (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 1,713 have no estimate.
https://portal.gdc.cancer.gov/files/4d181555-988a-4265-a3cd-6b2c1eb4889c

Most common (modal) total copy number across autosomal genes: 5 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 0: 349; copy number 1: 13; copy number 2: 2,629; copy number 3: 9,239; copy number 4: 5,321; copy number 5: 23,140; copy number 6: 9,796; copy number 7: 2,783; copy number 8: 2,779; copy number 9: 2,020; copy number 10: 125; copy number 11: 132; copy number 12: 2; copy number 13: 89; copy number 15: 36; copy number 16: 38; copy number 17: 158; copy number 18: 57; copy number 19: 55; copy number 20: 44; copy number 21: 10; copy number 22: 34; copy number 23: 11; copy number 28: 1; copy number 29: 5; copy number 31: 14; copy number 32: 30.

Homozygous deletions (total copy number 0; autosomes only): 27 genes in 4 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr9:21,966,929–21,967,751, 1 gene (within-gene range 0–3): CDKN2A-DT.
- chr21:9,026,821–9,908,010, 16 genes: CDRT15P9, CR392039.4, TEKT4P2, SOWAHCP2, CR392039.2, CR381653.1, SNX18P12, CR381653.2, NCOR1P4, AC124864.1, AC124864.2, U1, LINC01667, AC018692.2, RN7SL52P, SNORA70.
- chr21:22,008,756–22,884,000, 9 genes: LINC01687, LINC00308, AP000705.2, AP000705.1, RNU4-45P, AP000561.1, MAPK6P2, AP000959.1, AP000949.1.
- chr21:27,492,118–27,492,261, 1 gene: NCSTNP1.

Amplified relative to the modal value (total copy number ≥ 11, i.e. more than twice the modal value of 5; autosomes only): 715 genes in 18 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr3:130,048,143–130,055,920, 1 gene, copy number 17: AC083906.4.
- chr5:137,617,500–139,293,557, 43 genes, copy number 13 (within-gene range 3–13): KLHL3, MIR874, HNRNPA0, AC106791.2, NPY6R, AC106791.1, MYOT, PKD2L2, FAM13B, AC113382.1, AC113382.2, RNU6-1148P, WNT8A, NME5, RNU6-460P, RNU6-888P, BRD8, KIF20A, CDC23, GFRA3, RPS27AP18, CDC25C, FAM53C, AC104116.1, KDM3B, REEP2, AC113403.1, EGR1, RPL7P19, ETF1, HSPA9, SNORD63B, SNORD63, CTNNA1, AC113340.1, AC113340.2, AC034243.1, LRRTM2, SIL1, RNA5SP194, AC011405.1, RPL12P21, RNU6-572P.
- chr5:139,274,102–139,284,899, 3 genes, copy number 13 (within-gene range 3–13): SNHG4, SNORA74D, SNORA74A.
- chr8:30,237,382–39,417,378, 155 genes, copy number 11–29 (broad region; genes not listed).
- chr8:39,522,976–39,580,134, 1 gene, copy number 28: AC123767.1.
- chr8:116,642,130–128,220,803, 180 genes, copy number 12–31 (broad region; genes not listed).
- chr11:20,669,551–21,575,686, 1 gene, copy number 19 (within-gene range 9–19): NELL1.
- chr11:21,000,881–23,808,255, 29 genes, copy number 11–19: RNA5SP336, AC090857.1, AC090857.2, AC099730.1, RNA5SP337, ANO5, AC116534.1, AC107882.1, AC107886.1, AC104009.1, SLC17A6, AC040936.1, LINC01495, AC055878.1, FANCF, GAS2, RNA5SP338, SVIP, AC006299.1, CCDC179, LINC02718, AC100767.2, WIZP1, MIR8054, AC100767.1, THAP12P4, AC068472.1, LINC02726, AC100768.1.
- chr11:68,683,779–71,252,577, 61 genes, copy number 11–32 (within-gene range 4–32) (broad region; genes not listed).
- chr11:70,886,090–70,896,305, 1 gene, copy number 32: AP003783.1.
- chr13:31,483,414–31,803,389, 2 genes, copy number 16: AL161616.1, RXFP2.
- chr13:32,303,699–34,083,310, 30 genes, copy number 16: ZAR1L, BRCA2, IFIT1P1, N4BP2L1, AL137247.1, AL137247.2, N4BP2L2, ATP8A2P2, N4BP2L2-IT2, PDS5B, RNY1P4, AL138820.1, LINC00423, TOMM22P3, KL, STARD13, STARD13-IT1, STARD13-AS, AL627232.1, LINC02344, AL138999.2, AL138999.1, AL139383.1, AL161719.1, AL139081.1, RFC3, RNU5A-4P, AL161891.1, AL160394.2, VDAC1P12.
- chr13:34,910,545–36,297,842, 13 genes, copy number 15–21: Metazoa_SRP, AL138690.1, NBEA, SCAND3P1, PHBP13, MAB21L1, AL390071.1, LINC00445, DCLK1, SOHLH2, CCDC169-SOHLH2, CCDC169, RNU6-71P.
- chr13:73,399,031–73,661,891, 4 genes, copy number 16: AL162376.1, MARK2P12, LINC00393, LINC00392.
- chr14:23,938,219–24,052,555, 1 gene, copy number 11 (within-gene range 5–11): DHRS4-AS1.
- chr14:23,969,874–24,051,377, 2 genes, copy number 11 (within-gene range 5–11): DHRS4L2, AL136419.1.
- chr14:35,534,164–37,596,059, 43 genes, copy number 11–13 (within-gene range 8–13): INSM2, RALGAPA1, AL137818.1, QRSL1P3, AL162311.3, NUTF2P2, BRMS1L, AL162311.1, AL162311.2, AL133304.3, AL133304.1, ILF2P2, AL133304.2, LINC00609, PTCSC3, AL162511.1, RN7SKP21, MBIP, AL132857.1, DPPA3P2, RNU7-93P, SFTA3, SFTA3, NKX2-1, NKX2-1-AS1, PHKBP2, RPL29P3, NKX2-8, RN7SKP257, AL079303.1, PAX9, SLC25A21, AL162464.2, AL162464.1, MIR4503, AL079304.1, SLC25A21-AS1, RNU6-273P, MIPOL1, RNU6-886P, AL121790.2, AL121790.1, FOXA1.
- chr14:42,807,378–51,825,422, 145 genes, copy number 11–29 (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 8. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
